Surgical pathology report (de-identified scan), TCGA case TCGA-CN-4742, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-CN-4742-01A (Primary Tumor).

[page 1 of 10]
PATIENT HISTORY:

Squamous cell carcinoma of the tongue.

PRE-OP DIAGNOSIS: Squamous cell carcinoma of the tongue.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Glossectomy with right neck dissection.

FINAL DIAGNOSIS:

PART 1: LYMPH NODES AND SOFT TISSUE, LEFT NECK LEVEL 1, SELECTIVE DISSECTION –

- A. THREE LYMPH NODES, NO TUMOR PRESENT (0/3).
- B. SUBMANDIBULAR GLAND WITH NO SIGNIFICANT CHANGE.

PART 2: LYMPH NODES AND SOFT TISSUE, LEFT NECK LEVEL 2, SELECTIVE DISSECTION –

- A. THIRTEEN LYMPH NODES, NO SQUAMOUS CELL CARCINOMA PRESENT (0/13).
- B. THYROID TISSUE IN ONE LYMPH NODE (see comment).
- C. MINUTE FRAGMENTS OF ACCESSORY PAROTID TISSUE.

PART 3: LYMPH NODES, LEFT NECK LEVEL 3, SELECTIVE DISSECTION –

METASTATIC SQUAMOUS CELL CARCINOMA IN ONE OF ELEVEN LYMPH NODES (1/11) (<0.1 CM FOCUS).

PART 4: LYMPH NODE, LEFT NECK LEVEL 4, SELECTIVE DISSECTION –

ONE LYMPH NODE, NO TUMOR PRESENT (0/1).

PART 5: LYMPH NODES, RIGHT NECK LEVEL 2, SELECTIVE DISSECTION –

METASTATIC SQUAMOUS CELL CARCINOMA IN ONE OF EIGHT LYMPH NODES (1/8) (1.5 CM); NO EXTRACAPSULAR SPREAD.

PART 6: LYMPH NODE, RIGHT NECK LEVEL 4, SELECTIVE DISSECTION –

METASTATIC SQUAMOUS CELL CARCINOMA IN ONE OF SEVEN LYMPH NODES (1/7) (0.2 CM FOCUS); NO EXTRACAPSULAR SPREAD.

PART 7: LYMPH NODE AND SUBMANDIBULAR GLAND, RIGHT NECK LEVEL 1, SELECTIVE DISSECTION –

- A. UNREMARKABLE SUBMANDIBULAR GLAND.
- B. FIVE LYMPH NODES, NO TUMOR PRESENT (0/5).

PART 8: LYMPH NODE, RIGHT NECK LEVEL 3, SELECTIVE DISSECTION –

ONE LYMPH NODE, NO TUMOR PRESENT (0/1).

PART 9: RETROMOLAR REGION, RIGHT, BIOPSY –

ACUTE MUCOSITIS, FOCAL MILD DYSPLASIA, NO TUMOR PRESENT.

PART 10: TONGUE, NEAR TOTAL GLOSSECTOMY –

- A. INVASIVE SQUAMOUS CELL CARCINOMA (6.1 CM), KERATINIZING, MODERATELY TO POORLY DIFFERENTIATED, RIGHT, CROSSING MIDLINE.
-

[page 2 of 10]
Pathology Report

- B. PERINEURAL INVASION PRESENT.
- C. FOCAL EXTRINSIC MUSCLE INVOLVEMENT
- D. FINAL MARGINS FREE OF INVASIVE CARCINOMA (SEE ALSO PARTS 9, 11 TO 20).
- E. PATHOLOGIC STAGE pT4 N2B MX.

PART 11: NEW MARGIN, RIGHT RETROMOLAR REGION, BIOPSY –
SQUAMOUS CELL CARCINOMA IN SITU.

PART 12: MOLAR, RIGHT POSTERIOR, BIOPSY –
FOCAL SEVERE DYSPLASIA.

PART 13: SOFT PALATE ANTERIOR PILLAR, RIGHT, BIOPSY –
SEVERE DYSPLASIA.

PART 14: SOFT PALATE POSTERIOR PILLAR, RIGHT, BIOPSY –
SEVERE DYSPLASIA.

PART 15: PHARYNGO-EPIGLOTTIC FOLD, BIOPSY –
MILD-TO-MODERATE DYSPLASIA, NO TUMOR PRESENT.

PART 16: RIGHT VALLECULAR MARGIN, BIOPSY –
NO TUMOR PRESENT.

PART 17: BUCCAL GINGIVA, RIGHT, BIOPSY –
MILD DYSPLASIA, NO TUMOR PRESENT.

PART 18: RETROMOLAR TRIGONE, DEEP RIGHT MARGIN, BIOPSY –
NO TUMOR PRESENT.

PART 19: MOLAR SOCKET, RIGHT POSTERIOR, BIOPSY –
NO TUMOR PRESENT.

PART 20: NEW SOFT PALATE MARGIN, RIGHT ANTERIOR, BIOPSY –
MILD DYSPLASIA OF INVOLVING METAPLASTIC SALIVARY DUCT (ORIGINAL FROZEN SECTION ON LY) NO
TUMOR PRESENT.

PART 21: RETROMOLAR TRIGONE, RIGHT SUPERIOR, BIOPSY –
SQUAMOUS CELL CARCINOMA IN SITU.

PART 22: BUCCAL MUCOSA, RIGHT, BIOPSY –
NO TUMOR PRESENT.

PART 23: GINGIVA, RIGHT, BIOPSY –
NO TUMOR PRESENT.

PART 24: TONGUE BASE, RIGHT, BIOPSY –
NO TUMOR PRESENT.

[page 3 of 10]
Pathology Report

COMMENT:

Part 2: The thyroid tissue present in this lymph node extends into the parenchyma and shows focal nuclear features worrisome for papillary thyroid carcinoma. Thus, we would be reluctant to accept these as benign thyroid inclusions. If clinically indicated, work-up of this patient's thyroid should be performed.

MA/shm

My signature is attestation that I have personally reviewed the submitted material(s) and the final diagnosis reflects that evaluation.

GROSS DESCRIPTION:

The specimen is received in 24 parts.

Part 1 is identified as "left neck level 1" and is labeled by patient's name and initials [REDACTED]. It consists of a 4.8 x 3.2 x 1.6 cm aggregate of unremarkable fatty tissue, and a left submandibular gland (4.4 x 2.5 x 1.5 cm) that is tan and lobulated. The following sections were submitted:

1A - Bisected lymph nodes, left neck level 1

1B - Representative section of soft tissue and submandibular gland, left neck level 1.

Part 2 is labeled "left neck level 2" and is labeled with the patient's name and initials [REDACTED]. It consists of tan-yellow fatty tissue and attached soft, red skeletal muscle, (6 x 4.3 x 1.5 cm in aggregate). The following sections were submitted:

2A - Whole lymph nodes, left neck level 2

2B - Whole lymph nodes, left neck level 2

2C - Blood vessel, soft tissue, and whole lymph nodes, left neck level 2

Part 3 is labeled "left neck level 3" and is labeled with the patient's name and initials [REDACTED]. It consists of irregular, unoriented unremarkable fatty tissue and lymph nodes (2.9 cm x 2 cm x 1.9 cm in aggregate). The lymph nodes range from light tan to grey-red. The following sections were submitted:

3A - Soft tissue and whole lymph nodes

3B - Whole lymph nodes

Part 4 is labeled "left neck level 4" and consists of unremarkable-appearing skeletal muscle, one lymph node and soft tissue (4.5 x 3 x 1.2 cm in aggregate). The following sections were submitted:

4A - Representative section of soft tissue, with lymph node

Part 5 is labeled "right neck zone 2" and is identified by the patient's name and initials [REDACTED]. It consists of an aggregate of tissue (7 x 4.2 x 2.8 cm) with a firm, enlarged pink-grey lymph node (5 x 2.8 x 2.8 cm). This lymph node contains a tan-white encapsulated mass, 2 cm in diameter, with a friable cheesy-white center.

5A - Center of lymph node with encapsulated mass

5B - Whole lymph nodes

5C - Soft tissue, periphery of lymph node with encapsulated mass

Part 6 is labeled as "right neck level 4" and is labeled with the patient's name and initials [REDACTED]. It consists of a soft tissue aggregate (4.5 x 3.5 x 0.8 cm). There are embedded pink-tan lymph nodes up to 2.5 cm in length. The following sections were submitted:

[page 4 of 10]
Pathology Report

6A - Bisected lymph node
6B - Lymph nodes

Part 7 is labeled as "right neck level 1" and is identified by the patient's name and initials [REDACTED]. It consists of a soft tissue aggregate (5 x 3 x 1 cm). This aggregate also contains an unremarkable-appearing submandibular gland (3 x 2 x 1 cm). The following sections were submitted:

7A - Right submandibular gland
7B - Lymph nodes

Part 8 is labeled "Level 3 right neck" and is labeled with the patient's name and initials [REDACTED]. It consists of a 5.2 cm x 3 x 0.8 cm aggregate of fatty tissue, muscle. The following sections were submitted:

8A - Representative soft tissue and one bisected lymph node

Part 9 is labeled "Right retromolar trigone" and is identified by the patient's name and initials [REDACTED]. It consists of a single piece of tan white soft tissue (0.9 x 0.9 x 0.3 cm). Intraoperative consultation and frozen sections were requested for this specimen. It was submitted entirely in cassette 9AFS.

Part 10 is identified as "total glossectomy" and is labeled with the patient's name and initials [REDACTED]. It consists of a resected glottis with attached tumor and fatty tissue (8 x 7.2 x 7 cm). The specimen was bivalved along the longitudinal axis, revealing a poorly demarcated, soft, lobulated white nodule, 5.2 cm (anterior-posterior) x 5.5 cm (ventral-dorsal) x 6.1 cm (Right to Left). The following sections are submitted:

10A-10H representative sections of tumor from left lateral to right lateral.
10I - extra-glossal skeletal muscle, left
10J - extra-glossal skeletal muscle, right

Part 11 is identified as "New margin, right retromolar trigone" and is labeled with the patient's name and initials [REDACTED]. It consists of a 1.1 x 0.9 x 1.1 cm strip of soft tan tissue. Intraoperative consultation and frozen sections were requested for this specimen. It was submitted entirely in cassette 11AFS.

Part 12 is identified as "Right posterior molar" and is labeled with the patient's name and initials [REDACTED]. It consists of a tan fragment of tissue (1.2 x 0.8 x 0.2 cm). Intraoperative consultation and frozen sections were requested for this specimen. It was submitted entirely in cassette 12AFS.

Part 13 is identified as "right soft palate anterior pillar" and is labeled with the patient's name and initials [REDACTED]. It consists of a tan fragment of tissue (3 x 0.3 x 0.3 cm). Intraoperative consultation and frozen sections were requested for this specimen. It was submitted entirely in cassette 13AFS.

Part 14 is identified as "Right soft palate, posterior pillar" and is labeled with the patient's name and initials [REDACTED]. It consists of a tan, curved fragment of tissue (2.2 x 0.6 x 0.1 cm). Intraoperative consultation and frozen sections were requested for this specimen. It was submitted entirely in cassette 14AFS.

Part 15 is identified as "Pharyngoepiglottic fold" and is labeled with the patient's name and initials [REDACTED]. It consists of a tan fragment of tissue (1.2 x 0.8 x 0.2 cm). Intraoperative consultation and frozen sections were requested for this specimen. It was submitted entirely in cassette 15AFS.

Part 16 is identified as "right vallecular" and is labeled with the patient's name and initials [REDACTED]. It consists of a tan fragment of tissue measuring (1.2 x 0.4 x 0.3). Intraoperative consultation and frozen sections were requested for this specimen. It was submitted entirely in cassette 16AFS.

[page 5 of 10]
Pathology Report

Part 17 is identified as "Right buccal gingiva" and is labeled with the patient's name and initials [REDACTED]. It consists of a tan-pink fragment of tissue (1.5 x 1.1 x 0.4 cm). Intraoperative consultation and frozen sections were requested for this specimen. It was submitted entirely in cassette 17AFS.

Part 18 is identified as "right retromolar trigone deep margin" and is labeled with the patient's name and initials [REDACTED]. It consists of a tan fragment of tissue (0.6 x 0.5 x 0.4 cm). Intraoperative consultation and frozen sections were requested for this specimen. It was submitted entirely in cassette 18AFS.

Part 19 is identified as "right posterior molar socket" and is labeled with the patient's name and initials [REDACTED]. It consists of a tan fragment of tissue (0.3 x 0.3 x 0.2 cm). Intraoperative consultation and frozen sections were requested for this specimen. It was submitted entirely in cassette 12AFS.

Part 20 is identified as "new right soft palate anterior margin" and is labeled with the patient's name and initials [REDACTED]. It consists of a pink-tan fragment of tissue (1.3 x 0.6 x 0.4 cm). Intraoperative consultation and frozen sections were requested for this specimen. It was submitted entirely in cassette 20AFS.

Part 21 is identified as "right superior retromolar trigone" and is labeled with the patient's name and initials [REDACTED]. It consists of a fragment of tan tissue with brown foci (1.2 x 0.8 x 0.2 cm). It was submitted entirely in cassette 21A.

Part 22 is identified as "right buccal mucosa" and is labeled with the patient's name and initials [REDACTED]. It consists of a friable irregular tan mass with black foci, (0.7 x 0.4 x 0.2 cm). The specimen was entirely submitted in cassette 22A.

Part 23 is identified as "gingiva" and is labeled with the patient's name and initials [REDACTED]. It consists of a linear strip of tan tissue with a mottled brown-black-tan surface, (0.7 x 0.4 x 0.2 cm). The specimen was entirely submitted in cassette 23A.

Part 24 is identified as "left base of tongue" and is labeled with the patient's name and initials [REDACTED]. It consists of a 5 x 2.9 x 1.5 cm mottled piece of tan-brown tissue with irregular white foci. This specimen contains a blood vessel with cheesy white material protruding from it. A representative section from this tissue and blood vessel was submitted in cassette 24A.

Tumor has been procured for the Head and Neck SPORE Tissue Bank. The banked areas are inked red.

INTRAOPERATIVE CONSULTATION:

9AFS: RIGHT RETROMOLAR TRIGONE, BIOPSY.-

- A. BENIGN
- B. CHRONICALLY INFLAMED SQUAMOUS MUCOSA WITH FOCAL MILD-TO-MODERATE DYSPLASIA.
- C. NO INVASIVE TUMOR SEEN. [REDACTED]

11AFS. NEW MARGIN RIGHT RETROMOLAR TRIGONE, BIOPSY.-

- A. DEFER
- B. AT LEAST DYSPLASIA.
- C. POSSIBLE NECROTIZING SIALOMETAPLASIA.
- D. CANNOT RULE OUT INVASIVE DISEASE BECAUSE OF TANGENTIAL SECTIONING.

12AFS: RIGHT POSTERIOR MOLAR, BIOPSY.-

- A. MALIGNANT
- B. FOCAL MODERATE TO SEVERE DYSPLASIA.
- C. NO INVASIVE TUMOR SEEN. [REDACTED]

13AFS: RIGHT SOFT PALATE ANTERIOR PILLAR, BIOPSY.-

- A. MALIGNANT
- B. AT LEAST SEVERE DYSPLASIA.

[page 6 of 10]
[REDACTED]

Pathology Report

[REDACTED]

C. THE POSSIBILITY OF INVASIVE DISEASE CANNOT BE EXCLUDED. [REDACTED]

14AFS: RIGHT SOFT PALATE, POSTERIOR PILLAR, BIOPSY.-

- A. MALIGNANT
- B. FOCAL MODERATE TO SEVERE DYSPLASIA.
- C. NO INVASIVE TUMOR SEEN. ([REDACTED])

15AFS: PHARYNGOEPIGLOTTIC FOLD, BIOPSY.-

- A. BENIGN.
- B. NO TUMOR SEEN. [REDACTED]

16AFS: RIGHT VALLECULAR, BIOPSY.-

- A. BENIGN.
- B. NO TUMOR SEEN. [REDACTED]

17AFS: RIGHT BUCCAL GINGIVA, BIOPSY.-

- A. BENIGN
- B. NO TUMOR SEEN. ([REDACTED])

18AFS: RIGHT RETROMOLAR TRIGONE, DEEP MARGIN, BIOPSY.-

- A. BENIGN
- B. NO TUMOR SEEN.
- C. NO EPITHELIAL SURFACE IDENTIFIED. [REDACTED]

19AFS: RIGHT POSTERIOR MOLAR SOCKET, BIOPSY.-

- A. BENIGN.
- B. NO TUMOR SEEN. [REDACTED]

20AFS: NEW SITE SOFT PALATE ANTERIOR MARGIN, BIOPSY.-

- A. DEFER
- B. CHRONIC INFLAMMATION AND ATROPHY OF MINOR SALIVARY GLANDS AND FOCAL DYSPLASIA OF EPITHELIUM. OF MINOR SALIVARY GLAND DUCT.
- C. NO INVASIVE TUMOR SEEN.
- D. NO SURFACE EPITHELIUM. [REDACTED]

MICROSCOPIC:

Microscopic examination substantiates the above diagnosis.
[REDACTED]

The following statement applies to all immunohistochemistry, insitu hybridization (ISH & FISH), molecular anatomic pathology, and immunofluorescence testing:

The testing was developed and its performance characteristics determined by the [REDACTED] Department of Pathology, as required by the [REDACTED] regulations. The testing has not been cleared or approved for the specific use by the U.S. Food and Drug Administration, but the FDA has determined such approval is not necessary for clinical use. Tissue fixation ranges from a minimum of 2 to a maximum of 84 hours.

This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] ("CLIA") as qualified to perform high-complexity clinical testing. Pursuant to the requirements of CLIA, ASR's used in this laboratory have been established and verified for accuracy and precision. Additional information about this type of test is available upon request.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY UPPER AERODIGESTIVE TRACT AND SALIVARY GLAND TUMORS

[page 7 of 10]
Pathology Report

SPECIMEN TYPE: Resection: Glossectomy
TUMOR SITE: Oral Cavity
TUMOR SIZE: Greatest dimension: 6.1 cm
HISTOLOGIC TYPE: Squamous cell carcinoma, conventional
HISTOLOGIC GRADE: Other: Moderate-to-Poorly differentiated
PATHOLOGIC STAGING (pTNM): pT4a
pN2b
Number of regional lymph nodes examined: 59
Number of regional lymph nodes involved: 3
Extra-capsular extension of nodal tumor: Absent
pMX
MARGINS: Margins uninvolved by tumor
VENOUS/LYMPHATIC (LARGE/SMALL VESSEL) INVASION (V/L): Present
PERINEURAL INVASION: Present
ADDITIONAL PATHOLOGIC FINDINGS: None identified
Carcinoma in situ
Epithelial dysplasia

HISTO TISSUE SUMMARY/SLIDES REVIEWED:

Part 1: Left neck level 1

Stain/cht	Block
H&E x 1	A
H&E x 1	B

Part 2: Left neck level 2

Stain/cht	Block
H&E x 1	A
H&E x 1	B
H&E x 1	C

Part 3: Left neck level 3

Stain/cht	Block
H&E x 1	A
H&E x 1	B

Part 4: Left neck level 4

Stain/cht	Block
H&E x 1	A

Part 5: Zone 2 right neck

Stain/cht	Block
H&E x 1	A
H&E x 1	B
H&E x 1	C

[page 8 of 10]
Pathology Report

Part 6: Right neck level 4

Stain/cnt	Block
H&E x 1	A
H&E x 1	B

Part 7: Right neck level 1

Stain/cnt	Block
H&E x 1	A
H&E x 1	B

Part 8: Right neck level 3

Stain/cnt	Block
H&E x 1	A

Part 9: Right retromolar trigon

Stain/cnt	Block
H&E x 1	AFS

Part 10: Total glossectomy

Stain/cnt	Block
H&E x 1	A
H&E x 1	B
H&E x 1	C
H&E x 1	D
H&E x 1	E
H&E x 1	F
H&E x 1	G
H&E x 1	H
H&E x 1	I
H&E x 1	J

Part 11: New margin right retromolar trigon

Stain/cnt	Block
H&E x 1	A

Part 12: Right posterior molar

Stain/cnt	Block
H&E x 1	AFS

Part 13: Right soft palate anterior pillar

Stain/cnt	Block
H&E x 1	AFS

Part 14: Right soft palate posterior pillar

[page 9 of 10]
Pathology Report

Stain/cnt Block
H&E x 1 AFS

Part 15: Pharyngo-epiglottic fold

Stain/cnt Block
H&E x 1 AFS

Part 16: Right vallecular

Stain/cnt Block
H&E x 1 AFS

Part 17: Right buccal gingiva

Stain/cnt Block
H&E x 1 AFS

Part 18: Right retromolar trigon deep margin

Stain/cnt Block
H&E x 1 AFS

Part 19: Right posterior molar socket

Stain/cnt Block
H&E x 1 AFS

Part 20: New right soft palate anterior margin

Stain/cnt Block
H&E x 1 A

Part 21: Right superior retromolar trigon

Stain/cnt Block
H&E x 1 A

Part 22: Right buccal mucosa

Stain/cnt Block
H&E x 1 A

Part 23: Right alveola

Stain/cnt Block
H&E x 1 A

Part 24: Right base of tongue

Stain/cnt Block
H&E x 1 A

[page 10 of 10]
Pathology Report

ICD-9 Diagnosis Codes: {None Entered}

Source: NCI Genomic Data Commons file dca06396-a0d8-47ce-91b5-6095e6982608 (TCGA-CN-4742.43086B38-96A1-48FC-9B69-313ECB6642BF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).